Somatic mutation profile of tumor specimen C3L-03976-05 (aliquot CPT0231920006) from CPTAC case C3L-03976, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.4 years (23,885 days).
Specimen C3L-03976-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f3b04b-97c2-4dbb-98bf-c2ee530f02f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03976-31 (Blood Derived Normal), aliquot CPT0232040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da2ff9b-b202-4efb-8838-8e0a28fe3166

The open-access MAF lists 330 somatic variants for this specimen: 220 protein-altering or splice-affecting, 67 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 67, Nonsense Mutation 21, Intron 19, 5'UTR 10, RNA 7, Splice Site 5, Splice Region 4, 3'UTR 4, 5'Flank 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 462/931 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2
- ACP1 | c.231+4C>A | Splice Region (SNP) | VAF 18/540 reads (3%) | catalogued as COSV99681814; called by muse, mutect2
- ACSM2A | c.1609C>A p.P537T (on ENST00000219054; = p.P458T on NM_001308169.2) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54583083; called by muse, mutect2
- ADAMTS6 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV66856785; called by muse, mutect2
- AMPH | c.505-1G>A p.X169_splice | Splice Site (SNP) | VAF 11/117 reads (9%) | catalogued as COSV100341259; called by muse, mutect2
- ARHGAP15 | c.1280C>A p.T427K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV54483751; called by muse, mutect2, varscan2
- ASB4 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV57945785; called by muse, mutect2
- BCAS3 | c.1846A>T p.I616F (on ENST00000390652 / NM_001353144.2; = p.I601F on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV66776316; called by muse, mutect2
- CAPS2 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60824539; called by muse, mutect2
- CLDN18 | c.159C>A p.C53* | Nonsense Mutation (SNP) | VAF 21/303 reads (7%) | catalogued as COSV51737798; called by muse, mutect2
- CSF2RB | c.2162C>A p.P721Q | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as rs777520373; called by muse, mutect2
- DCAF4L2 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV60479321, COSV60482779; called by muse, mutect2
- DCLK1 | c.2201G>T p.R734L (on ENST00000360631 / NM_001330072.2; = p.R427L on NM_001195416.2) | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.931); catalogued as COSV55169757; called by muse, mutect2
- DLL1 | c.135C>G p.C45W | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64538950; called by muse, mutect2
- DMRTB1 | c.962-2A>T p.X321_splice | Splice Site (SNP) | VAF 10/193 reads (5%) | catalogued as COSV65113859; called by muse, mutect2
- DNAH5 | c.5892C>G p.I1964M | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54203943; called by muse, mutect2
- DNAH8 | c.3663G>A p.M1221I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59460276, COSV59486547; called by muse, mutect2
- EEF2 | c.2489G>T p.R830L | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs758028986, COSV100501054, COSV58579844; called by muse, mutect2
- ENPP2 | c.1933G>C p.V645L (on ENST00000075322 / NM_001040092.3; = p.V697L on NM_006209.5) | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50010024, COSV50030870; called by muse, mutect2, varscan2
- ERCC6 | c.3467A>G p.K1156R | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs755899444; called by muse, mutect2
- FANK1 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV64156130, COSV64156194; called by muse, mutect2
- FBLN1 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53052113; called by muse, mutect2
- FCRL4 | c.1250-2A>G p.X417_splice | Splice Site (SNP) | VAF 34/351 reads (10%) | catalogued as COSV99619157; called by muse, mutect2
- HTR1A | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as COSV60501495; called by muse, mutect2
- IFI27 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407819698; called by muse, mutect2
- IFI44L | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 7/117 reads (6%) | catalogued as COSV60727253; called by muse, mutect2
- INPPL1 | c.222T>A p.D74E | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs986113353; called by muse, mutect2
- KCNIP1 | c.344G>T p.G115V (on ENST00000411494 / NM_001034837.3; = p.G104V on NM_014592.4) | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200199892; called by muse, mutect2, varscan2
- KIAA0408 | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100847592; called by muse, mutect2
- KRT76 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 42/509 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs747106936, COSV100196683; called by muse, mutect2
- LOXHD1 | c.2677G>C p.V893L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769899814, COSV100191506; called by muse, mutect2
- LRP5 | c.3797G>T p.C1266F | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53711665; called by muse, mutect2, varscan2
- MRC2 | c.747C>A p.Y249* | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | catalogued as COSV57636183; called by muse, mutect2
- MRGPRF | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as rs866254239; called by muse, mutect2, varscan2
- MUC16 | c.24794C>G p.S8265C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as rs745523804; called by muse, mutect2
- MYH3 | c.2887G>A p.A963T | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1264242216; called by muse, mutect2
- NCAM2 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV53067931, COSV53105528; called by muse, mutect2
- NDRG1 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV60484231; called by muse, mutect2
- NIPAL2 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 19/177 reads (11%) | catalogued as COSV57838479; called by muse, mutect2, varscan2
- NLRC5 | c.3635A>T p.E1212V | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as rs764182772; called by muse, mutect2
- NLRP12 | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 38/517 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs756022301; called by muse, mutect2
- NPC1L1 | c.3541G>T p.G1181C | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99203424; called by muse, mutect2
- NTRK2 | c.1768G>T p.E590* (on ENST00000323115 / NM_001369534.1; = p.E606* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/306 reads (9%) | catalogued as COSV52879250; called by muse, mutect2
- OR13A1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1334879701, COSV65572354, COSV65573278; called by muse, mutect2
- OR5AS1 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.672); catalogued as COSV100546397; called by muse, mutect2
- OR5H2 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62350439; called by muse, mutect2
- PAGE2B | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100894279; called by muse, mutect2
- PAPPA2 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV62776064; called by muse, mutect2
- PCDHA2 | c.1535C>A p.A512E | Missense Mutation (SNP) | VAF 56/764 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100973719; called by muse, mutect2
- PIP5K1B | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1334033392; called by muse, mutect2
- PLK3 | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV59499068; called by muse, mutect2
- PLXNA1 | c.4649A>T p.K1550M | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780420538; called by muse, mutect2
- PPP1R14D | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54544525; called by muse, mutect2
- PSG6 | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 25/330 reads (8%) | catalogued as COSV51831131, COSV51833294; called by muse, mutect2
- REG1B | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59308247; called by muse, mutect2, varscan2
- RGS6 | c.393T>C p.Y131= | Splice Region (SNP) | VAF 11/201 reads (5%) | catalogued as rs1213939817; called by muse, mutect2
- RIMBP2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs915996535; called by muse, mutect2
- RIMS2 | c.4237G>T p.D1413Y (on ENST00000666250 / NM_001348490.2; = p.D984Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51693873; called by muse, mutect2
- SLC6A5 | c.2319G>T p.M773I | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100116957; called by muse, mutect2
- SRSF11 | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 11/216 reads (5%) | catalogued as COSV63937728; called by muse, mutect2
- SYCP2L | c.873G>C p.R291S | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs762865074, COSV51655071; called by muse, mutect2
- SYNE1 | c.11215G>T p.D3739Y (on ENST00000367255 / NM_182961.4; = p.D3724Y on NM_033071.3) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55111084; called by muse, mutect2
- TMCO4 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV53869429; called by muse, mutect2
- TTC8 | c.713A>G p.Y238C (on ENST00000338104 / NM_001288781.1; = p.Y222C on NM_144596.4) | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1257221355, COSV57631004; called by muse, mutect2
- YIPF7 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60656114; called by muse, mutect2
- ZNF536 | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62820033; called by muse, mutect2
- ZNF628 | c.1738A>C p.N580H | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs902594112; called by muse, mutect2
- ZNF695 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60587835; called by muse, mutect2, varscan2
- ZNF716 | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV101348593, COSV104435559; called by muse, mutect2
- ABCA6 | c.4437G>T p.L1479F | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ABCB5 | c.2829A>T p.L943F (on ENST00000404938 / NM_001163941.2; = p.L498F on NM_178559.6) | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ABI1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACAN | c.4564G>T p.V1522L | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- ACP1 | c.231+3A>T | Splice Region (SNP) | VAF 17/539 reads (3%) | called by muse, mutect2
- ADAMTS3 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2
- ADAMTS7 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADCY8 | c.2503-2A>T p.X835_splice | Splice Site (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- ADGRB1 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ADGRG3 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER3 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); called by muse, mutect2
- AP1G1 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APC | c.4434G>T p.R1478S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ARHGEF9 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ASF1A | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- AVPR2 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL3 | c.3145A>T p.K1049* | Nonsense Mutation (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- CCDC153 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); called by muse, mutect2
- CCDC85A | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, mutect2
- CCIN | c.798C>A p.C266* | Nonsense Mutation (SNP) | VAF 23/248 reads (9%) | called by muse, mutect2
- CD36 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- CHD2 | c.5153+7A>G | Splice Region (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- CHRDL2 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2
- CHST7 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CNBD2 | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- CNTN5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/61 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CNTN5 | c.1225T>A p.W409R | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- CNTNAP5 | c.850A>T p.T284S | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- CTNND2 | c.3164G>T p.R1055L | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); called by muse, mutect2
- DCSTAMP | c.820A>T p.R274W | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- DSP | c.6309G>T p.K2103N | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- DTNA | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- DYTN | c.1598A>T p.K533I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- EDARADD | c.193C>A p.P65T (on ENST00000334232 / NM_145861.4; = p.P55T on NM_080738.4) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2
- EFCAB9 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- EPB41L1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 36/600 reads (6%) | called by muse, mutect2
- EPB41L3 | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.418); called by muse, mutect2
- EXO1 | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 24/317 reads (8%) | called by muse, mutect2
- FAM237A | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FAS | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FCN1 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- FOXL1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2
- FOXL1 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2
- FSTL1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.651); called by muse, mutect2
- GARRE1 | c.1635G>T p.K545N | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- GAS7 | c.1030A>G p.T344A (on ENST00000432992 / NM_201433.2; = p.T204A on NM_003644.3) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- GCM2 | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2
- GFRA1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- GLT8D1 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); called by muse, mutect2
- GPD1L | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2
- GPR82 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.129); called by muse, mutect2
- GRIN2A | c.3352T>A p.Y1118N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GRM8 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2
- H2BC7 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- HOXA3 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2
- IKZF2 | c.1448A>T p.H483L | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2
- IL1B | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2
- INPPL1 | c.223G>T p.G75* | Nonsense Mutation (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- IPO13 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- IQCN | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- ITGB5 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- ITIH6 | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.097); called by muse, mutect2
- JPH1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNB2 | c.1515C>A p.N505K | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KCNJ8 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0100 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- KIF4B | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIR3DL1 | c.582A>T p.R194S | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KLB | c.2134G>C p.A712P | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- KLHL30 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP29-1 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LRFN2 | c.1438A>C p.N480H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- LRRC14B | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- LZTS3 | c.1196A>G p.D399G (on ENST00000329152; = p.D353G on NM_001282533.2) | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- MAGEA6 | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2
- MAGI2 | c.3659G>T p.R1220L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGI3 | c.2312A>T p.D771V | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAST4 | c.4334A>T p.Q1445L (on ENST00000403625 / NM_001164664.2; = p.Q1256L on NM_015183.3) | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM2 | c.4115T>A p.L1372* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- MGAM2 | c.4759G>A p.V1587I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMP20 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- MRC1 | c.3892G>T p.G1298* | Nonsense Mutation (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- MRTFA | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- MS4A6A | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.057); called by muse, mutect2
- MYADM | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- MYH7 | c.4935C>G p.S1645R | Missense Mutation (SNP) | VAF 50/476 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MYO10 | c.4704G>T p.E1568D | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- N4BP2 | c.2655G>T p.W885C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- NAGS | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NALCN | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2
- NBEAL2 | c.7332C>A p.H2444Q | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- NEU2 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.1); called by muse, mutect2
- NLRP7 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- OBSCN | c.12414G>T p.E4138D | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.253); called by muse, mutect2
- OR8D2 | c.573C>A p.S191R | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); called by muse, mutect2
- OSGIN2 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCDH12 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB13 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 58/738 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); called by muse, mutect2
- PCDHGA4 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB4 | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCMTD1 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- PDE1C | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGAM4 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- PLOD2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- PNLIPRP2 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPRC1 | c.3505G>T p.A1169S | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRSS41 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- PYY | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- RAB3GAP2 | c.1771A>G p.K591E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- RAD51AP2 | c.3248-1G>T p.X1083_splice | Splice Site (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- RAD51D | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RESP18 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- REXO1 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- RPE65 | c.299T>A p.I100K | Missense Mutation (SNP) | VAF 31/327 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SAGE1 | c.1183C>A p.R395S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); called by muse, mutect2
- SEC14L1 | c.1942A>T p.S648C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SIAE | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC25A13 | c.1201G>C p.V401L | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2
- SLC32A1 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC5A8 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- SLC7A3 | c.93C>A p.C31* | Nonsense Mutation (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2
- SMO | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMPD3 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SMURF1 | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX4 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SP5 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- SPAM1 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2
- SPATA16 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2
- SST | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- STYXL1 | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SYPL2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- TCAF1 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEX13C | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TEX2 | c.1762A>G p.I588V | Missense Mutation (SNP) | VAF 35/460 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2
- TGM1 | c.673C>G p.R225G | Missense Mutation (SNP) | VAF 32/598 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.671); called by muse, mutect2
- TMEM132B | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TMEM244 | c.107G>C p.C36S | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- TNK2 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); called by muse, mutect2
- TNR | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2
- TNRC18 | c.4438G>C p.E1480Q | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TRIM51GP | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2
- TXNDC2 | c.1408C>A p.L470M (on ENST00000306084 / NM_001098529.2; = p.L403M on NM_032243.6) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- UNC45B | c.2078A>T p.K693M | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- VWA3A | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- WTIP | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2
- XG | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); called by muse, mutect2
- ZCCHC8 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.219); called by muse, mutect2
- ZMYND15 | c.1675C>A p.L559M (on ENST00000433935 / NM_001136046.3; = p.L520M on NM_032265.2) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.248); called by muse, mutect2
- ZNF331 | c.1039A>T p.R347W | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL1 | c.1212G>A p.V404= | Silent (SNP) | VAF 24/403 reads (6%) | called by muse, mutect2
- AHCTF1 | c.1620A>G p.K540= (on ENST00000366508; = p.K514= on NM_015446.5) | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- AJM1 | c.1284C>T p.H428= | Silent (SNP) | VAF 40/444 reads (9%) | catalogued as rs1286185224; called by muse, mutect2
- AKAIN1 | c.126G>A p.Q42= | Silent (SNP) | VAF 9/232 reads (4%) | catalogued as rs1555609158; called by muse, mutect2
- AMPD1 | c.390C>A p.S130= | Silent (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- ANKRD33B | c.1047G>T p.R349= | Silent (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- ARHGEF28 | c.375G>T p.T125= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55256019; called by muse, mutect2, varscan2
- ART5 | c.426G>A p.Q142= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- AXIN2 | c.1092C>T p.P364= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as rs765518896, COSV61055180; ClinVar: likely benign; called by muse, mutect2
- BMP7 | c.921C>A p.P307= | Silent (SNP) | VAF 25/471 reads (5%) | called by muse, mutect2
- BTN1A1 | c.1452C>A p.V484= | Silent (SNP) | VAF 20/319 reads (6%) | called by muse, mutect2
- CCR1 | c.222G>C p.L74= | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- CDH18 | c.1792C>A p.R598= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as COSV56915596; called by muse, mutect2
- CEP120 | c.1602A>G p.L534= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1354378913; called by muse, mutect2
- CHST6 | c.774C>A p.L258= | Silent (SNP) | VAF 60/656 reads (9%) | catalogued as COSV59999817; called by muse, mutect2
- COL24A1 | c.1665C>T p.G555= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- COL27A1 | c.441C>T p.F147= | Silent (SNP) | VAF 23/314 reads (7%) | catalogued as rs575113764; called by muse, mutect2
- CRB2 | c.3543C>A p.P1181= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100749465; called by muse, mutect2
- CSMD3 | c.5169C>A p.V1723= (on ENST00000297405 / NM_001363185.1; = p.V1619= on NM_052900.3) | Silent (SNP) | VAF 11/268 reads (4%) | catalogued as COSV52096568; called by muse, mutect2
- CTH | c.882G>T p.L294= | Silent (SNP) | VAF 16/280 reads (6%) | called by muse, mutect2
- DUSP23 | c.126G>T p.L42= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- ENTHD1 | c.336T>A p.A112= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV57318049; called by muse, mutect2
- ESM1 | c.78G>A p.V26= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- F13A1 | c.1764G>T p.V588= | Silent (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- FAT2 | c.3432C>T p.P1144= | Silent (SNP) | VAF 16/219 reads (7%) | called by muse, mutect2
- FMN2 | c.423G>T p.V141= | Silent (SNP) | VAF 15/199 reads (8%) | catalogued as rs769498638; called by muse, mutect2
- FREM3 | c.894C>T p.G298= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as rs1462304106, COSV61681529; called by muse, mutect2
- GCNT4 | c.861C>T p.I287= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as COSV59281313; called by muse, mutect2
- HECW1 | c.225G>T p.S75= | Silent (SNP) | VAF 16/400 reads (4%) | called by muse, mutect2
- ICE1 | c.5571A>G p.P1857= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as rs1373514211; called by muse, mutect2
- IGHV4-34 | c.267C>A p.L89= | Silent (SNP) | VAF 33/554 reads (6%) | called by muse, mutect2
- KANSL1 | c.2811G>A p.V937= (on ENST00000574590 / NM_001193465.2; = p.V938= on NM_015443.4) | Silent (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- KIF2B | c.915G>T p.T305= | Silent (SNP) | VAF 18/274 reads (7%) | catalogued as COSV52136241; called by muse, mutect2
- LYN | c.951C>A p.I317= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1282536785, COSV101319594; called by muse, mutect2
- LYPD2 | c.120C>A p.I40= | Silent (SNP) | VAF 26/412 reads (6%) | catalogued as COSV63649328; called by muse, mutect2
- MASP1 | c.1158C>T p.L386= | Silent (SNP) | VAF 24/398 reads (6%) | catalogued as rs749873757; called by muse, mutect2
- MGAM | c.4893C>A p.V1631= | Silent (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- MGME1 | c.213G>A p.S71= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- MLN | c.45A>G p.V15= | Silent (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- MYO3A | c.972G>C p.T324= | Silent (SNP) | VAF 27/286 reads (9%) | called by muse, mutect2
- MYOD1 | c.468T>C p.Y156= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as COSV51454025; called by muse, mutect2
- NANOS3 | c.195C>T p.G65= (on ENST00000397555; = p.G84= on NM_001098622.2) | Silent (SNP) | VAF 16/317 reads (5%) | catalogued as rs935939442, COSV59248689; called by muse, mutect2
- OGFRL1 | c.1155C>T p.S385= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100965799; called by muse, mutect2
- OR13C5 | c.600T>G p.L200= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- OR2T8 | c.72C>G p.V24= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2, varscan2
- PARVG | c.123C>A p.P41= | Silent (SNP) | VAF 9/218 reads (4%) | called by muse, mutect2
- PCDHA1 | c.1977G>C p.L659= | Silent (SNP) | VAF 23/349 reads (7%) | called by muse, mutect2
- PCDHB1 | c.546C>A p.T182= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as rs781838912; called by muse, mutect2
- PCDHB12 | c.1128G>A p.G376= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as COSV99507975; called by muse, mutect2
- PCDHGB3 | c.1260G>A p.V420= | Silent (SNP) | VAF 28/330 reads (8%) | called by muse, mutect2
- PIP4K2A | c.1050G>A p.K350= | Silent (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- PKHD1L1 | c.354G>T p.G118= | Silent (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- POTEJ | c.2556C>T p.L852= | Silent (SNP) | VAF 40/738 reads (5%) | called by muse, mutect2
- PTCH1 | c.3591C>T p.S1197= | Silent (SNP) | VAF 34/394 reads (9%) | catalogued as COSV59462551; called by muse, mutect2
- RBM42 | c.747A>G p.E249= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- RBP3 | c.2079G>T p.V693= | Silent (SNP) | VAF 21/302 reads (7%) | called by muse, mutect2
- RGS5 | c.501G>T p.L167= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- SERPINB13 | c.840G>A p.K280= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- SLC25A45 | c.660G>T p.T220= | Silent (SNP) | VAF 26/253 reads (10%) | catalogued as COSV53684847; called by muse, mutect2, varscan2
- SLC6A9 | c.1224C>G p.V408= (on ENST00000360584 / NM_201649.4; = p.V354= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- SPDEF | c.774G>A p.L258= | Silent (SNP) | VAF 15/331 reads (5%) | called by muse, mutect2
- SYNE1 | c.11214A>T p.V3738= (on ENST00000367255 / NM_182961.4; = p.V3723= on NM_033071.3) | Silent (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- TAF6L | c.1374C>A p.T458= | Silent (SNP) | VAF 21/340 reads (6%) | called by muse, mutect2
- TCEAL4 | c.318A>T p.P106= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- TRBV24-1 | c.174A>T p.P58= | Silent (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- UGT2A2 | c.465G>T p.V155= | Silent (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- USH2A | c.9513G>A p.V3171= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- AC009093.9 | chr16:29074997 C>T | 5'Flank (SNP) | VAF 13/210 reads (6%) | called by muse, mutect2
- AC092818.1 | n.293G>T | RNA (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- ADAM28 | c.2178+45C>A | Intron (SNP) | VAF 16/282 reads (6%) | catalogued as COSV56102439; called by muse, mutect2
- ARHGAP40 | c.*506C>T | 3'UTR (SNP) | VAF 13/230 reads (6%) | catalogued as rs1307834873, COSV54807429; called by muse, mutect2
- ARL6IP4 | c.1209+29G>T | Intron (SNP) | VAF 24/229 reads (10%) | catalogued as COSV54896035; called by muse, mutect2, varscan2
- BCORP1 | n.3615G>A | RNA (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- CAMK2B | c.415-1465C>A | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- CCL21 | c.372-20C>A | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- CD200 | chr3:112333148 T>A | 5'Flank (SNP) | VAF 42/432 reads (10%) | called by muse, mutect2
- CD81 | c.182-125G>T | Intron (SNP) | VAF 9/291 reads (3%) | called by muse, mutect2
- CPA6 | c.838+44A>T | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- DNLZ | c.228+70G>T | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- FAM21FP | n.943C>T | RNA (SNP) | VAF 21/384 reads (5%) | called by muse, mutect2
- FOXP2 | c.*3000T>A | 3'UTR (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- FUS | c.1169-27G>C | Intron (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- GNG2 | c.-109A>T | 5'UTR (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- IGFBP3 | c.-118C>A | 5'UTR (SNP) | VAF 18/220 reads (8%) | catalogued as COSV51873547; called by muse, mutect2
- IGHV1-45 | c.-10G>T | 5'UTR (SNP) | VAF 14/222 reads (6%) | catalogued as rs782728770; called by muse, mutect2
- KCNMA1 | c.2267-7520G>A | Intron (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- LGR5 | c.-70G>A | 5'UTR (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- LRP1B | c.13247+871G>T | Intron (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- MARK4 | c.1494+110C>T | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- NDUFB1 | chr14:92121766 C>A | 5'Flank (SNP) | VAF 18/418 reads (4%) | called by muse, mutect2
- NFYC-AS1 | n.322G>T | RNA (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- NTRK2 | c.1397-56628G>T | Intron (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- OR2W5 | n.935G>T | RNA (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- PALLD | c.1965-13007C>A | Intron (SNP) | VAF 15/410 reads (4%) | called by muse, mutect2
- PATE2 | c.-17C>T | 5'UTR (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- PAX2 | c.-26C>G | 5'UTR (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- PAX4 | c.-35G>A | 5'UTR (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- RCC1 | c.-323A>T | 5'UTR (SNP) | VAF 18/305 reads (6%) | called by muse, mutect2
- RNF217-AS1 | n.2361C>A | RNA (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- RNF7 | c.176-834G>T | Intron (SNP) | VAF 10/237 reads (4%) | called by muse, mutect2
- SKP2 | c.8+22G>T | Intron (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- SLC34A1 | c.*13G>T | 3'UTR (SNP) | VAF 42/339 reads (12%) | called by muse, mutect2, varscan2
- SP9 | c.-29C>A | 5'UTR (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- SSPOP | n.11972C>T | RNA (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- TEX35 | c.586+445C>A | Intron (SNP) | VAF 17/238 reads (7%) | called by muse, mutect2
- THSD4 | c.1016-70188G>A | Intron (SNP) | VAF 16/507 reads (3%) | catalogued as rs1283482807; called by muse, mutect2
- TTYH1 | c.126+1182C>T | Intron (SNP) | VAF 29/292 reads (10%) | catalogued as rs1379614496; called by muse, mutect2, varscan2
- ZFHX4 | c.3093+27G>C | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- ZIC3 | c.*16C>T | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- ZNF735 | c.-23G>T | 5'UTR (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
